Somatic mutation profile of tumor specimen TCGA-HZ-7925-01A (aliquot TCGA-HZ-7925-01A-11D-2154-08) from TCGA case TCGA-HZ-7925, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 66.1 years (24,150 days).
Specimen TCGA-HZ-7925-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea212cb7-e06c-41c2-ae40-ac93c55b19ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HZ-7925-10A (Blood Derived Normal), aliquot TCGA-HZ-7925-10A-01D-2154-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/70d89b69-dda2-484c-8587-12ed449e0ba7

The open-access MAF lists 29 somatic variants for this specimen: 19 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 9, Frame Shift Ins 3, Nonsense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 15/140 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.405C>A p.C135* | Nonsense Mutation (SNP) | VAF 25/205 reads (12%) | hotspot (GDC flag); catalogued as COSV52665429, COSV52669330, COSV52682693, COSV52815283; called by muse, mutect2, varscan2
- CPEB4 | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 84/567 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as rs1429463154, COSV54176628, COSV99437608; called by muse, mutect2, varscan2
- DISC1 | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 32/394 reads (8%) | SIFT tolerated (0.95); PolyPhen benign (0.005); catalogued as rs367543086, COSV54419467; ClinVar: not provided; called by muse, mutect2
- HOXA3 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 86/795 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.139); catalogued as rs745318781, COSV100415279, COSV57826478; called by muse, mutect2, varscan2
- KCNH1 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 160/692 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs769735609, COSV99657389; called by muse, mutect2, varscan2
- L1CAM | c.871C>T p.Q291* | Nonsense Mutation (SNP) | VAF 221/896 reads (25%) | catalogued as CM138917, COSV62827560; called by muse, mutect2, varscan2
- L3HYPDH | c.565G>A p.G189S | Missense Mutation (SNP) | VAF 57/356 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1417911825, COSV55966830; called by muse, mutect2, varscan2
- NAALAD2 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 72/697 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs761176623, COSV58958461; called by muse, mutect2, varscan2
- OR51F2 | c.846T>G p.F282L | Missense Mutation (SNP) | VAF 26/542 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV100437890; called by muse, mutect2
- PCDHA8 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 123/1137 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65332452; called by muse, mutect2, varscan2
- PHACTR1 | c.1351C>T p.R451W | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as rs370759003; called by muse, mutect2
- TNXB | c.4991G>A p.R1664H (on ENST00000647633; = p.R1417H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/939 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs777054871, COSV100925873; called by muse, mutect2
- TRPM6 | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 56/481 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1407266718, COSV62511825; called by muse, mutect2, varscan2
- USH2A | c.1097A>G p.N366S | Missense Mutation (SNP) | VAF 55/472 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV100229241; called by muse, mutect2, varscan2
- ZC3H11A | c.384G>T p.Q128H | Missense Mutation (SNP) | VAF 56/629 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100142155; called by muse, mutect2
- KANSL1 | c.2869dup p.Q957Pfs*16 (on ENST00000574590 / NM_001193465.2; = p.Q958Pfs*16 on NM_015443.4) | Frame Shift Ins (INS) | VAF 47/415 reads (11%) | called by mutect2, pindel, varscan2
- SMAD4 | c.904+1_904+2dup | Frame Shift Ins (INS) | VAF 46/354 reads (13%) | called by mutect2, pindel, varscan2
- ZAN | c.2631dup p.L878Tfs*13 | Frame Shift Ins (INS) | VAF 82/630 reads (13%) | called by mutect2, varscan2
- CENPT | c.1065C>G p.P355= | Silent (SNP) | VAF 172/1302 reads (13%) | called by muse, mutect2, varscan2
- CTSG | c.273G>A p.A91= | Silent (SNP) | VAF 106/476 reads (22%) | catalogued as rs533433194, COSV53536485; called by muse, mutect2, varscan2
- GIT2 | c.1089G>A p.S363= (on ENST00000355312 / NM_057169.5; = p.S365= on NM_014776.5) | Silent (SNP) | VAF 16/200 reads (8%) | catalogued as rs374462464, COSV58080772; called by muse, mutect2
- IFNL1 | c.51C>T p.A17= | Silent (SNP) | VAF 51/436 reads (12%) | catalogued as rs768571570, COSV100373614; called by muse, mutect2, varscan2
- NCKAP5 | c.1701C>T p.G567= | Silent (SNP) | VAF 63/502 reads (13%) | catalogued as COSV100490086; called by muse, mutect2, varscan2
- RASGRF1 | c.2247G>A p.S749= | Silent (SNP) | VAF 57/517 reads (11%) | catalogued as rs140968213; called by muse, mutect2, varscan2
- SYT3 | c.820C>T p.L274= | Silent (SNP) | VAF 87/691 reads (13%) | catalogued as COSV100143883; called by muse, mutect2, varscan2
- TLN2 | c.1671G>A p.T557= | Silent (SNP) | VAF 43/276 reads (16%) | catalogued as rs747382018, COSV100168035; called by muse, mutect2, varscan2
- TRGV4 | c.147C>T p.G49= | Silent (SNP) | VAF 85/579 reads (15%) | called by muse, mutect2, varscan2
- TTN | c.10303+2267A>G | Intron (SNP) | VAF 26/226 reads (12%) | catalogued as COSV100594927; called by muse, mutect2, varscan2
